TCGA case TCGA-IB-7886 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f73dfd7f-e054-46ff-9485-e8d05afe2da6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 80 years; Vital status: Dead; Days to death: 123 days; Cause of death: Not Cancer Related; Cause of death source: Medical Record.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 80.3 years (29,319 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 123 days; Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 11; Tumor largest dimension diameter: 6 cm.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 123 days; Disease response: Tumor Free.

Exposures
- Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Alcohol drinks per day: 2; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 35; Tobacco smoking onset year: 1975.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-7886-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 1.1; Shortest dimension: 0.2.
  Slide TCGA-IB-7886-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-IB-7886-01A-01-BS1: Section location: Bottom; Percent tumor cells: 68; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 30.
- Sample TCGA-IB-7886-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-7886-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Anatomic organ subdivision: Head of Pancreas; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor resected max dimension: 6.0; Tumor status: Tumor free; Cause of death: Other, non-malignant disease; Tobacco smoking history indicator: 2; Alcohol exposure intensity: Daily Drinker; Alcohol consumption frequency: 7; Diabetes diagnosis indicator: No; History chronic pancreatitis: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Cause of death: Other, non-malignant disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 123 days; disease-specific survival: no event (censored), 123 days; disease-free interval: no event (censored), 123 days; progression-free interval: no event (censored), 123 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-7886-01A-11D-2153-01): tumor purity 0.51, ploidy 2.63, whole-genome doublings 1.
